Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5511, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5511-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] of PSA value of 9.7 and other PSA of 6.71 in [REDACTED]. The patient also has a history of biopsy on [REDACTED] this biopsy reveals: Prostatic adenocarcinoma, Gleason score 3+4 = 7 in the right side of the prostate. The patient also has a history [REDACTED]

[REDACTED] DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

[REDACTED] CGA - EJ - 5511

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN FIVE (5) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN TEN (10) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7 WITH TERTIARY GLEASON PATTERN 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.6 cm.
- C. THE CARCINOMA INVOLVES 20% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE RIGHT ANTERIOR BASE, RIGHT POSTERIOR BASE AND RIGHT LEVEL 7 REGION (SLIDES 3Q, 3Y AND 3QQ).
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- H. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: pT3a N0 Mx.
- L. TNM HISTOLOGIC GRADE = G4.
- M. BENIGN PROSTATIC HYPERTROPHY.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 9.7
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	40%
WEIGHT OF PROSTATE:	47.70gm
TUMOR SIZE:	Maximum dimension: 1.6 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	15
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMx
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 12bb1c02-f784-40cc-ad1a-598a231af378 (TCGA-EJ-5511.4E4D79FC-ECC3-4533-AC69-9BDEC44A080C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).